Somatic mutation profile of tumor specimen MMRF_1749_1_BM_CD138pos (aliquot MMRF_1749_1_BM_CD138pos_T1_KBS5U_K11935) from MMRF case MMRF_1749, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.7 years (19,264 days).
Specimen MMRF_1749_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fa2f5ac-b0f2-4430-b9c2-1666d7b61359.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1749_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1749_1_PB_Whole_C4_KBS5U_K11902; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c595a9a-9d1f-41b7-9bb1-66284f0625b4

The open-access MAF lists 56 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Intron 11, 3'UTR 10, Silent 5, Frame Shift Del 3, 5'Flank 3, 5'UTR 2, Nonsense Mutation 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APPL2 | c.263A>G p.Y88C | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs372091392; called by muse, mutect2, varscan2
- DRG2 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56728190; called by muse, mutect2, varscan2
- GRK6 | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100586840; called by muse, mutect2, varscan2
- IGHV5-51 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 102/115 reads (89%) | SIFT tolerated (0.72); PolyPhen benign (0.131); catalogued as rs1555541633; called by muse, varscan2
- IGLV3-1 | c.65A>C p.E22A | Missense Mutation (SNP) | VAF 56/62 reads (90%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as rs528877557; called by muse, mutect2, varscan2
- IGLV3-1 | c.302A>C p.E101A | Missense Mutation (SNP) | VAF 65/76 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs532827838; called by muse, mutect2, varscan2
- RTN4RL1 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 85/171 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as rs377049572; called by muse, mutect2, varscan2
- ACTL7B | c.673G>C p.A225P | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF33 | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.605); called by muse, mutect2
- BRIP1 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- C16orf86 | c.932dup p.L312Afs*21 | Frame Shift Ins (INS) | VAF 50/83 reads (60%) | called by mutect2, pindel, varscan2
- CRMP1 | c.368G>C p.W123S | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DOP1A | c.4201A>C p.N1401H | Missense Mutation (SNP) | VAF 122/252 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- EID2B | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FBXO4 | c.267G>A p.W89* | Nonsense Mutation (SNP) | VAF 62/145 reads (43%) | called by muse, mutect2, varscan2
- MEP1A | c.899T>C p.V300A | Missense Mutation (SNP) | VAF 98/212 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYEOV | c.207G>T p.E69D | Missense Mutation (SNP) | VAF 83/180 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- PCLO | c.13697A>C p.K4566T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBL1XR1 | c.1237del p.M414Cfs*2 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- TMIGD1 | c.125T>G p.L42R | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRAF3 | c.1688_1694delinsGG p.S563Wfs*23 | Frame Shift Del (DEL) | VAF 78/92 reads (85%) | called by pindel, varscan2*
- TRIM37 | c.2788G>C p.V930L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR82 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.26); called by muse, mutect2
- ZNF292 | c.2415_2416del p.T806Vfs*4 | Frame Shift Del (DEL) | VAF 85/211 reads (40%) | called by mutect2, pindel, varscan2
- ANKFN1 | c.435C>A p.V145= | Silent (SNP) | VAF 33/68 reads (49%) | called by muse, mutect2
- CPLX3 | c.138G>A p.E46= | Silent (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- PAPPA | c.2643T>C p.C881= | Silent (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- SMARCA5 | c.2133T>C p.V711= | Silent (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- WDPCP | c.1392C>T p.L464= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as rs770628323, COSV55412080; called by muse, mutect2, varscan2
- AHI1 | c.135+702T>A | Intron (SNP) | VAF 89/183 reads (49%) | called by muse, mutect2
- AL353743.4 | n.1046G>A | RNA (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- ANKRD17 | c.4401+671A>T | Intron (SNP) | VAF 4/69 reads (6%) | called by muse, mutect2
- ATF2 | c.627-178C>T | Intron (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021040 T>A | 5'Flank (SNP) | VAF 68/81 reads (84%) | catalogued as rs532073995, COSV104379272; called by muse, mutect2, varscan2
- CDC7 | c.*52A>G | 3'UTR (SNP) | VAF 20/22 reads (91%) | called by muse, mutect2, varscan2
- CDH19 | c.*1721del | 3'UTR (DEL) | VAF 46/105 reads (44%) | catalogued as rs963609378; called by mutect2, pindel, varscan2
- CNOT6 | c.*3672T>A | 3'UTR (SNP) | VAF 50/112 reads (45%) | called by muse, mutect2, varscan2
- COL4A3 | c.610-28T>C | Intron (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- DIPK2A | c.657+214del | Intron (DEL) | VAF 145/360 reads (40%) | called by mutect2, pindel, varscan2
- DOCK1 | c.610-97T>C | Intron (SNP) | VAF 29/39 reads (74%) | catalogued as rs556237798; called by muse, mutect2, varscan2
- E2F6 | c.*1577C>A | 3'UTR (SNP) | VAF 67/171 reads (39%) | called by muse, mutect2, varscan2
- GASK1B | c.*1859T>G | 3'UTR (SNP) | VAF 51/104 reads (49%) | called by muse, mutect2, varscan2
- GNA12 | c.526-29666A>C | Intron (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- GULP1 | c.843+1290A>G | Intron (SNP) | VAF 71/182 reads (39%) | called by muse, mutect2, varscan2
- IRF4 | c.*3827_*3828del | 3'UTR (DEL) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- ISL1 | c.*1097A>T | 3'UTR (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- KIAA0232 | c.-149_-137del | 5'UTR (DEL) | VAF 30/83 reads (36%) | called by mutect2, pindel, varscan2
- NR5A2 | c.*2668G>T | 3'UTR (SNP) | VAF 20/22 reads (91%) | called by muse, mutect2, varscan2
- NRXN1 | c.*1653G>A | 3'UTR (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- OPRM1 | c.1165-10535C>T | Intron (SNP) | VAF 35/91 reads (38%) | called by muse, mutect2, varscan2
- RPS8 | c.211+114G>A | Intron (SNP) | VAF 8/10 reads (80%) | called by muse, mutect2, varscan2
- SLC44A1 | c.*8242C>T | 3'UTR (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975306 T>G | 5'Flank (SNP) | VAF 119/133 reads (89%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975607 T>C | 5'Flank (SNP) | VAF 97/109 reads (89%) | catalogued as COSV104432393; called by muse, mutect2, varscan2
- TUBA4A | c.227-30A>G | Intron (SNP) | VAF 31/76 reads (41%) | called by muse, mutect2, varscan2
- ZFPM2 | c.-6G>C | 5'UTR (SNP) | VAF 36/40 reads (90%) | catalogued as COSV68285446; called by muse, varscan2
